Somatic mutation profile of tumor specimen TCGA-OR-A5K9-01A (aliquot TCGA-OR-A5K9-01A-11D-A29I-10) from TCGA case TCGA-OR-A5K9, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 61.9 years (22,596 days).
Specimen TCGA-OR-A5K9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 802c6ea3-0090-4805-83eb-6ec0faa6d376.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5K9-11A (Solid Tissue Normal), aliquot TCGA-OR-A5K9-11A-11D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55a41b06-160d-4b67-a912-aefaf44e5523

The open-access MAF lists 142 somatic variants for this specimen: 104 protein-altering or splice-affecting, 31 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 31, Nonsense Mutation 7, Intron 3, 5'Flank 2, Frame Shift Del 2, 5'UTR 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133_156del p.S45_P52del | In Frame Del (DEL) | VAF 48/137 reads (35%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ABCB5 | c.3101G>A p.R1034H (on ENST00000404938 / NM_001163941.2; = p.R589H on NM_178559.6) | Missense Mutation (SNP) | VAF 89/231 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs960822608, COSV51702454; called by muse, mutect2, varscan2
- ABCC11 | c.4004G>C p.R1335P | Missense Mutation (SNP) | VAF 124/444 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100750470; called by muse, mutect2
- ABCF1 | c.2117C>T p.T706M (on ENST00000326195 / NM_001025091.2; = p.T668M on NM_001090.3) | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs746522355; called by muse, mutect2, varscan2
- ARFGEF3 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 207/624 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs772700641; called by muse, mutect2, varscan2
- C7 | c.1544G>A p.G515E | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.873); catalogued as COSV57474117; called by muse, varscan2
- CNTNAP4 | c.2466G>C p.K822N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56680760; called by muse, mutect2, varscan2
- CSAD | c.706G>A p.A236T (on ENST00000444623 / NM_001244705.2; = p.A263T on NM_015989.5) | Missense Mutation (SNP) | VAF 89/328 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.18); catalogued as rs921031738; called by muse, mutect2, varscan2
- DNAH7 | c.6216G>C p.W2072C | Missense Mutation (SNP) | VAF 73/212 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56766878; called by muse, mutect2, varscan2
- DTL | c.1032G>A p.W344* | Nonsense Mutation (SNP) | VAF 42/156 reads (27%) | catalogued as rs763877768, COSV100877160; called by muse, mutect2, varscan2
- ECHDC3 | c.887C>G p.P296R | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64867903; called by muse, mutect2, varscan2
- ERBB4 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 109/440 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); catalogued as rs1451769238, COSV53575391; called by muse, mutect2, varscan2
- ERCC6 | c.1449G>T p.E483D | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV63392719; called by muse, mutect2, varscan2
- ESYT1 | c.58C>G p.P20A | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV57272202; called by muse, mutect2
- EXD2 | c.1630G>C p.A544P (on ENST00000312994 / NM_001193362.1; = p.A419P on NM_018199.3) | Missense Mutation (SNP) | VAF 62/231 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57282742; called by muse, mutect2, varscan2
- FAM9A | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV66813751; called by muse, mutect2, varscan2
- FANCI | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV104406977; called by muse, mutect2, varscan2
- FRMPD4 | c.2243C>T p.A748V | Missense Mutation (SNP) | VAF 85/162 reads (52%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as rs370344979, COSV66213661; called by muse, mutect2, varscan2
- GALNT12 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.999); catalogued as rs762155395; called by muse, mutect2, varscan2
- GRIN3A | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs145326290, COSV62450102; called by muse, mutect2, varscan2
- H3C10 | c.5C>G p.A2G | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.682); catalogued as rs778245917; called by muse, mutect2, varscan2
- HUNK | c.1961C>G p.P654R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99528231; called by muse, mutect2, varscan2
- KCNJ6 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 5/71 reads (7%) | catalogued as COSV99898907; called by muse, mutect2
- KCNK7 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs1242005113; called by muse, mutect2
- KIAA1549 | c.2464del p.V822Cfs*17 | Frame Shift Del (DEL) | VAF 24/133 reads (18%) | catalogued as COSV54318391; called by mutect2, pindel, varscan2
- KIF13B | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1276999381; called by muse, mutect2, varscan2
- KIF25 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 116/366 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.722); catalogued as rs536727400; called by muse, mutect2, varscan2
- KRTAP10-9 | c.307G>A p.V103I | Missense Mutation (SNP) | VAF 121/473 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs782122695, COSV100551310; called by muse, mutect2, varscan2
- LRRC4B | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV65349270; called by muse, mutect2, varscan2
- MCM9 | c.220C>G p.R74G | Missense Mutation (SNP) | VAF 102/165 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as rs760702305; called by muse, mutect2, varscan2
- MN1 | c.3745G>A p.E1249K | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as rs761317200; called by muse, mutect2, varscan2
- MYMK | c.522G>A p.W174* | Nonsense Mutation (SNP) | VAF 32/103 reads (31%) | catalogued as rs754740828; called by muse, mutect2
- MYT1L | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 148/233 reads (64%) | SIFT tolerated (0.3); PolyPhen benign (0.087); catalogued as rs1195801769; called by muse, mutect2, varscan2
- NLGN4X | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 82/175 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs758529208, COSV52003690; called by muse, mutect2, varscan2
- OLFML2B | c.1588G>A p.V530I | Missense Mutation (SNP) | VAF 82/359 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as rs749921063, COSV54193595; called by muse, mutect2, varscan2
- OR2T33 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 298/793 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs138653777; called by muse, mutect2, varscan2
- PTGS2 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as rs919237837; called by muse, mutect2, varscan2
- RANBP2 | c.3409C>T p.P1137S | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs762754314, COSV99313602; called by muse, mutect2, varscan2
- RELN | c.3311G>C p.G1104A | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV58986070; called by muse, mutect2, varscan2
- REV3L | c.5654del p.P1885Qfs*45 | Frame Shift Del (DEL) | VAF 49/129 reads (38%) | catalogued as COSV100725173; called by mutect2, pindel, varscan2
- RFX2 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.15); catalogued as rs948583093; called by muse, mutect2, varscan2
- SMPD4 | c.1966G>A p.E656K (on ENST00000409031 / NM_017951.4; = p.E627K on NM_017751.4) | Missense Mutation (SNP) | VAF 96/404 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.638); catalogued as COSV60078937; called by muse, mutect2, varscan2
- TAZ | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 97/239 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782173851, COSV54796646; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRAF3IP3 | c.782C>A p.S261Y | Missense Mutation (SNP) | VAF 77/297 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as rs755767725; called by muse, varscan2
- UPF1 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 114/184 reads (62%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.012); catalogued as COSV53194211; called by muse, mutect2
- UPK3A | c.136C>A p.L46I | Missense Mutation (SNP) | VAF 97/192 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.066); catalogued as COSV99343138; called by muse, mutect2, varscan2
- VXN | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs765020183; called by muse, mutect2, varscan2
- XPO7 | c.1780G>A p.G594R | Missense Mutation (SNP) | VAF 51/238 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53018433; called by muse, mutect2, varscan2
- ADGRV1 | c.6733G>T p.E2245* | Nonsense Mutation (SNP) | VAF 38/119 reads (32%) | called by muse, mutect2, varscan2
- AEBP1 | c.1667C>A p.A556D | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.179); called by muse, mutect2
- AKAP8L | c.1391A>C p.Q464P | Missense Mutation (SNP) | VAF 44/583 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.184); called by muse, mutect2
- ARL13A | c.94T>C p.S32P | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- BCHE | c.541T>C p.F181L | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1QC | c.307G>C p.G103R | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CEP350 | c.1908G>C p.Q636H | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CNTD1 | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT tolerated (0.23); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- CSMD1 | c.4853T>G p.V1618G (on ENST00000520002; = p.V1617G on NM_033225.6) | Missense Mutation (SNP) | VAF 13/315 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.03); called by muse, mutect2
- CSMD2 | c.5015T>C p.V1672A | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- CYP4A22 | c.1324C>A p.Q442K | Missense Mutation (SNP) | VAF 32/253 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- DCLK1 | c.1163A>G p.E388G | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- DHRS9 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 79/240 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ENTPD4 | c.238A>G p.T80A | Missense Mutation (SNP) | VAF 97/455 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPN3 | c.110G>T p.S37I | Missense Mutation (SNP) | VAF 101/119 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FKBP4 | c.1148A>G p.Y383C | Missense Mutation (SNP) | VAF 82/135 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- GNB1 | c.862G>T p.G288W | Missense Mutation (SNP) | VAF 86/176 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- HMGCS2 | c.1306G>C p.D436H | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ITCH | c.2533C>G p.L845V (on ENST00000262650 / NM_001257137.3; = p.L804V on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- KIF2C | c.1724C>T p.T575I | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KRTAP11-1 | c.107G>T p.C36F | Missense Mutation (SNP) | VAF 77/327 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- MAGIX | c.380A>T p.E127V | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MICAL2 | c.3991G>C p.A1331P | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- NDUFB8 | c.15G>T p.R5S | Missense Mutation (SNP) | VAF 106/172 reads (62%) | SIFT tolerated (0.44); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- NFE2 | c.1088T>C p.V363A | Missense Mutation (SNP) | VAF 75/233 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- NOS3 | c.1585G>T p.G529C | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOTCH4 | c.4656G>T p.W1552C | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- NPSR1 | c.138C>G p.Y46* | Nonsense Mutation (SNP) | VAF 58/214 reads (27%) | called by muse, mutect2
- OR51A4 | c.707T>G p.L236R | Missense Mutation (SNP) | VAF 302/648 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- OSBP2 | c.751A>T p.S251C | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PAK3 | c.1322C>T p.P441L (on ENST00000262836 / NM_001324328.2; = p.P426L on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PDZRN3 | c.1484A>G p.N495S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PKHD1 | c.10190A>T p.Q3397L | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PPP1R18 | c.1544T>C p.L515P | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- PRKCQ | c.701T>A p.F234Y | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- PTCD1 | c.187A>T p.T63S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PUDP | c.163T>G p.L55V | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RB1CC1 | c.2755G>T p.E919* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- RCAN2 | c.283G>T p.G95* | Nonsense Mutation (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- RP1L1 | c.5752G>A p.E1918K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- RRM2 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RYR3 | c.8949A>T p.K2983N (on ENST00000389232; = p.K2984N on NM_001036.6) | Missense Mutation (SNP) | VAF 60/66 reads (91%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SLC16A7 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 44/698 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SLC26A2 | c.948G>C p.L316F | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- SLC4A2 | c.2624G>C p.R875T | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM86B | c.276C>G p.I92M | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TNXB | c.9090G>T p.R3030S (on ENST00000647633; = p.R2783S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/340 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- UGT2A3 | c.44T>A p.L15H | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- UNC5CL | c.169A>C p.T57P | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- VILL | c.1443C>A p.F481L | Missense Mutation (SNP) | VAF 100/260 reads (38%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- WDR44 | c.1274C>A p.T425K | Missense Mutation (SNP) | VAF 139/357 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- WDR45 | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 53/101 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- ZNF607 | c.1482A>G p.I494M | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF639 | c.1096A>G p.T366A | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ZNF653 | c.1663C>T p.P555S | Missense Mutation (SNP) | VAF 102/241 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZPLD1 | c.278T>C p.I93T (on ENST00000466937 / NM_001329788.1; = p.I109T on NM_175056.2) | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ABCA7 | c.1773C>T p.L591= | Silent (SNP) | VAF 86/625 reads (14%) | called by muse, mutect2
- ATP13A4 | c.1827A>G p.T609= | Silent (SNP) | VAF 69/147 reads (47%) | called by muse, mutect2, varscan2
- ATP8A2 | c.1443C>A p.P481= | Silent (SNP) | VAF 32/81 reads (40%) | called by muse, mutect2, varscan2
- BAZ2A | c.1407C>T p.V469= | Silent (SNP) | VAF 42/330 reads (13%) | called by muse, mutect2, varscan2
- C10orf90 | c.426C>T p.I142= | Silent (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- CACNG3 | c.90G>A p.T30= | Silent (SNP) | VAF 58/222 reads (26%) | catalogued as rs767505349, COSV50064101; called by muse, mutect2, varscan2
- CCT3 | c.249T>A p.I83= | Silent (SNP) | VAF 22/75 reads (29%) | called by muse, mutect2, varscan2
- COLEC12 | c.840C>T p.N280= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs370741108; called by muse, mutect2, varscan2
- DMD | c.10161G>A p.A3387= | Silent (SNP) | VAF 54/124 reads (44%) | catalogued as rs773387358; called by muse, varscan2
- GNB1 | c.861T>G p.A287= | Silent (SNP) | VAF 90/180 reads (50%) | called by muse, mutect2, varscan2
- HECTD4 | c.13053T>G p.G4351= | Silent (SNP) | VAF 106/375 reads (28%) | called by muse, mutect2, varscan2
- ITGAM | c.1170C>T p.I390= | Silent (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- KIF7 | c.2526T>C p.L842= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV101067319; called by muse, mutect2, varscan2
- MFSD3 | c.903C>A p.V301= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV56743295, COSV56743997; called by muse, mutect2
- MGRN1 | c.1272C>T p.S424= | Silent (SNP) | VAF 69/110 reads (63%) | catalogued as rs577424986; called by muse, mutect2, varscan2
- MRGPRE | c.30C>T p.H10= | Silent (SNP) | VAF 52/56 reads (93%) | catalogued as rs530383366; called by muse, mutect2, varscan2
- NCAM1 | c.1575C>G p.A525= (on ENST00000316851 / NM_181351.5; = p.A515= on NM_000615.7) | Silent (SNP) | VAF 116/267 reads (43%) | called by muse, mutect2, varscan2
- PPARD | c.279G>T p.G93= | Silent (SNP) | VAF 38/84 reads (45%) | called by muse, mutect2, varscan2
- PTPRC | c.2668C>A p.R890= | Silent (SNP) | VAF 66/313 reads (21%) | catalogued as COSV61407958; called by muse, mutect2, varscan2
- PTPRT | c.4071C>T p.V1357= | Silent (SNP) | VAF 85/300 reads (28%) | called by muse, mutect2, varscan2
- RPS28 | c.54G>C p.L18= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV56846897; called by muse, mutect2, varscan2
- RSPO2 | c.561T>C p.C187= | Silent (SNP) | VAF 58/273 reads (21%) | called by muse, mutect2, varscan2
- SAE1 | c.687A>G p.A229= | Silent (SNP) | VAF 36/151 reads (24%) | called by muse, mutect2, varscan2
- SELL | c.942C>G p.T314= (on ENST00000650983; = p.T301= on NM_000655.5) | Silent (SNP) | VAF 57/246 reads (23%) | catalogued as COSV99357658; called by muse, mutect2, varscan2
- SLC23A1 | c.1083C>T p.F361= | Silent (SNP) | VAF 22/218 reads (10%) | catalogued as rs886323791; called by muse, mutect2, varscan2
- SPC25 | c.166C>A p.R56= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV99960382; called by muse, mutect2, varscan2
- UGT2A3 | c.45C>G p.L15= | Silent (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- USP39 | c.1518C>T p.D506= | Silent (SNP) | VAF 79/287 reads (28%) | catalogued as rs145807458; called by muse, mutect2, varscan2
- ZFP28 | c.1614T>C p.C538= | Silent (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- ZMAT1 | c.1086G>A p.Q362= | Silent (SNP) | VAF 16/122 reads (13%) | called by muse, mutect2, varscan2
- ZNF846 | c.717A>G p.S239= | Silent (SNP) | VAF 25/85 reads (29%) | called by muse, mutect2, varscan2
- CUTA | chr6:33418153 G>A | 5'Flank (SNP) | VAF 17/199 reads (9%) | catalogued as rs757702543; called by muse, mutect2, varscan2
- CUTA | chr6:33418154 C>G | 5'Flank (SNP) | VAF 16/220 reads (7%) | catalogued as rs746349836; called by muse, mutect2
- EPRS1 | c.-1G>T | 5'UTR (SNP) | VAF 64/265 reads (24%) | called by muse, mutect2, varscan2
- ERCC6 | c.1397+8364G>T | Intron (SNP) | VAF 17/57 reads (30%) | catalogued as rs757845558; called by muse, mutect2, varscan2
- LINC02872 | n.279G>T | RNA (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- PCDHGA4 | c.2514+20G>A | Intron (SNP) | VAF 17/98 reads (17%) | catalogued as rs773379210; called by muse, mutect2, varscan2
- SYTL2 | c.1460-3191G>C | Intron (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
